Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3VD, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3VD-01A (Primary Tumor).

[page 1 of 5]
Neck
and Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Thyroid nodules / papillary thyroid carcinoma.

Specimens Submitted:

- 1: Right paratracheal lymph node, excision (fs)
- 2: R/O right upper parathyroid, excision (fs)
- 3: Additional right paratracheal lymph nodes, excision
- 4: Left Left paratracheal lymph nodes, excision
- 5: Additional left paratracheal lymph nodes
- 6: Total thyroid, thyroidectomy
- 7: Left paratracheal lymph nodes #3 (three)
- 8: Right paratracheal lymph nodes #3 (three)

DIAGNOSIS:

1. Right paratracheal lymph node, excision (fs):
Part # 1

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 2
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.5cm.
Size of the largest metastatic focus: 0.1 cm.
Extranodal extension is not identified

ICD-O-3

carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS C73.9

5-2-12
20

2. Right upper parathyroid; biopsy:
- Unremarkable parathyroid tissue
3. Additional right paratracheal lymph nodes; excision:
- Five benign lymph nodes (0/5)
4. Left Left paratracheal lymph nodes; excision:
- Benign fibroadipose tissue
5. Additional left paratracheal lymph nodes; excision:
- Three benign lymph nodes (0/3)
6. Total thyroid, thyroidectomy:
Part # 6
Tumor Type:
Papillary microcarcinoma

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

[page 2 of 5]
Other Tumor Features:

Calcification of non-psammoma type
Psammoma bodies

Tumor Location:

Isthmus

Tumor Size:

Greatest diameter is 0.8 cm.

Tumor Encapsulation:

None Identified

Blood Vessel Invasion:

Not Identified

Extrathyroid Extension:

Not Identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not Identified

Adenoma(s) (away from the carcinoma):

Not Identified

Non-Neoplastic Thyroid:

Exhibits severe chronic lymphocytic thyroiditis

Parathyroid Glands:

Identified

One normocellular parathyroid gland adjacent to the right lobe

7. Left paratracheal lymph nodes #3 (three):

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma

Number of lymph nodes examined: 4

Number of lymph nodes with metastatic disease: 4

Size of the largest lymph node involved by tumor: 0.9cm.

Size of the largest metastatic focus : 0.5 cm.

Extranodal extension is not identified

8. Right paratracheal lymph nodes #3 (three); biopsy:

- Benign fibroadipose tissue

- No lymph node present

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). the specimen is received fresh, labeled "right paratracheal nodule" and consists of two lymph nodes 0.5x0.5x0.3cm each.
Submitted entirely for frozen

[page 3 of 5]
Summary of sections:
FSC -frozen

2). The specimen is received fresh, labeled "R/O right upper parathyroid" and consists of one piece of soft pink tissue measuring 0.1x0.1x0.1 cm and weighing less than 0.001gm. Submitted entirely for frozen

Summary of sections:
FSC -frozen

3). The specimen is received in formalin in, labeled "additional right paratracheal lymph node", and consists of two tan firm lymph nodes ranging from 0.3 - 1.2 cm in greatest dimension. Both lymph nodes are submitted in their entirety.

Summary of sections:
LN - lymph nodes

4). The specimen is received in formalin, labeled "Left paratracheal lymph nodes" and consists of an irregular fragment of soft tissue measuring 0.6 x 0.6 x 0.2 cm. The specimen is entirely submitted.

Summary of sections:
U-- undesignated

5). The specimen is received in formalin, labeled "additional left paratracheal lymph nodes", and consists of a possible lymph node measuring 0.6 cm in greatest dimension. It is submitted entirely.

Summary of sections:
LN - lymph nodes

6). The specimen is received fresh, labeled total thyroid, stitch marks right lobe, and consists of a thyroid weighing 17g. The right lobe measures 4.4 by 1.9 x 1.4 cm, the left lobe measures 4.6 by 2.0 x 1.3 cm and the isthmus measures 2.1 x 1.5 by 1.2 cm. A pyramidal lobe is present measuring 1.1 by 0.6 x 0.2 cm. A longitudinal defect is present in the isthmus. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a nodule within the isthmus. It measures 1.2 x 0.8 x 0.6. cm and display a tan soft homogeneous cut surface. The remaining thyroid parenchyma is red brown and unremarkable. Skeletal muscle is present on the anterior surface. Representative sections of the specimen submitted for . The specimen is entirely submitted.

Summary of sections:
N - nodule
RL - right lobe
LL - left lobe
IS - isthmus

7). The specimen is received in formalin, labeled "left paratracheal lymph nodes number three", and consists of four tan firm lymph nodes ranging from 0.4 to 0.8 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:
LN - lymph nodes

8). The specimen is received in formalin, labeled "right paratracheal lymph node number three", and consists of a piece of adipose tissue measuring 1.0 cm in greatest dimension. Specimen is entirely submitted.

Summary of sections:

[page 4 of 5]
AD - adipose tissue

Summary of Sections:

Part 1: Right paratracheal lymph node, excision (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: R/O right upper parathyroid, excision (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 3: Additional right paratracheal lymph nodes, excision

Block	Sect. Site	PCs
1	LN	2

Part 4: Left Left paratracheal lymph nodes, excision

Block	Sect. Site	PCs
1	U	1

Part 5: Additional left paratracheal lymph nodes

Block	Sect. Site	PCs
1	LN	2

Part 6: Total thyroid, thyroidectomy

Block	Sect. Site	PCs
2	IS	3
6	LL	7
2	N	3
9	RL	11

Part 7: Left paratracheal lymph nodes #3 (three)

Block	Sect. Site	PCs
1	LN	2

Part 8: Right paratracheal lymph nodes #3 (three)

Block	Sect. Site	PCs
1	AD	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Right paratracheal lymph node (fs): Metastatic carcinoma.
Permanent Diagnosis: same
2. Frozen Section Diagnosis: R/O right upper parathyroid (fs): Parathyroid tissue,
Permanent Diagnosis: same

Source: NCI Genomic Data Commons file 74f43a95-997c-46f9-9e04-50157100b80e (TCGA-DJ-A3VD.B31A3265-AA77-431E-9886-403254D1B8A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).